Somatic mutation profile of tumor specimen MMRF_2602_1_BM_CD138pos (aliquot MMRF_2602_1_BM_CD138pos_T1_KHS5U_L12922) from MMRF case MMRF_2602, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.9 years (18,956 days).
Specimen MMRF_2602_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe4eebaa-46fd-433d-b416-b599e909b0c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2602_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2602_1_PB_WBC_C3_KHS5U_L12923; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2b19826-25d3-4a86-b67e-9ed7f4f4010c

The open-access MAF lists 95 somatic variants for this specimen: 37 protein-altering or splice-affecting, 12 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 26, Silent 12, Intron 9, 5'UTR 4, 5'Flank 3, 3'Flank 3, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRD1 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1430866436; called by muse, mutect2, varscan2
- AGTR1 | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV62558999; called by muse, mutect2, varscan2
- AHSG | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99889929; called by muse, mutect2, varscan2
- BAHCC1 | c.6208G>A p.A2070T | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs782177105; called by muse, mutect2, varscan2
- DCHS1 | c.8399C>T p.S2800L | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.514); catalogued as rs748609148; called by muse, mutect2, varscan2
- DSCAML1 | c.971G>A p.R324Q (on ENST00000321322; = p.R264Q on NM_020693.4) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.999); catalogued as rs1485165144, COSV100355808; called by muse, mutect2, varscan2
- EGR1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs201259281; called by muse, mutect2, varscan2
- IGF2BP1 | c.242G>C p.R81P | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV99288688; called by muse, mutect2, varscan2
- IGLV3-25 | c.139C>G p.P47A | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs182727015; called by muse, mutect2
- ITGB4 | c.5065G>A p.A1689T | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372938774; called by muse, mutect2
- LEMD2 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs200171402; called by muse, mutect2, varscan2
- MET | c.462A>G p.I154M | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs771146873, COSV99041945; called by muse, mutect2, varscan2
- OGDHL | c.2489G>A p.R830Q | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs772974122; called by muse, mutect2, varscan2
- OR1S1 | c.822C>A p.F274L | Missense Mutation (SNP) | VAF 97/318 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as rs747800347, COSV58706665; called by muse, mutect2, varscan2
- PACS2 | c.716T>C p.I239T | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.48); catalogued as rs1399881176; called by muse, mutect2, varscan2
- PLXNB2 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs767968899; called by muse, mutect2, varscan2
- RTEL1 | c.3545C>T p.S1182L | Missense Mutation (SNP) | VAF 67/274 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.278); catalogued as rs770535334; called by muse, mutect2, varscan2
- SEL1L3 | c.157T>C p.Y53H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.133); catalogued as COSV104393910; called by muse, mutect2, varscan2
- TMEM134 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as rs555090402; called by muse, mutect2, varscan2
- ZEB1 | c.2869G>A p.E957K | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100313755; called by muse, mutect2, varscan2
- ZNF280B | c.1207T>C p.Y403H | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1569172681; called by muse, mutect2, varscan2
- ANKRD30A | c.1331A>G p.K444R (on ENST00000611781; = p.K388R on NM_052997.2) | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ASB3 | c.132G>T p.W44C | Missense Mutation (SNP) | VAF 102/455 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC141 | c.4514C>G p.P1505R | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- CDH2 | c.1976-2A>C p.X659_splice | Splice Site (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- DCX | c.262A>C p.T88P | Missense Mutation (SNP) | VAF 55/79 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNMT3A | c.502G>C p.G168R | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ERLIN2 | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FLG | c.11753T>G p.V3918G | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- IGLV3-1 | c.52G>T p.V18L | Missense Mutation (SNP) | VAF 62/108 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.026); called by mutect2, varscan2
- MBD3 | c.408G>C p.Q136H | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFX1 | c.2881G>C p.A961P | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PRKCE | c.1479C>A p.D493E | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SNX25 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SPATA31E1 | c.2620A>G p.T874A | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SULT1C4 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USH1C | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA13 | c.14391C>T p.G4797= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as rs751959837; called by muse, mutect2, varscan2
- ARHGEF4 | c.1854C>T p.I618= | Silent (SNP) | VAF 34/82 reads (41%) | called by muse, varscan2
- COIL | c.192G>A p.G64= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as rs879515648; called by muse, mutect2
- CST9 | c.12G>C p.P4= | Silent (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- FASN | c.969C>T p.G323= | Silent (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- HIVEP1 | c.7167G>A p.Q2389= | Silent (SNP) | VAF 80/243 reads (33%) | called by muse, mutect2, varscan2
- IGHV1-69 | c.228A>T p.T76= | Silent (SNP) | VAF 60/175 reads (34%) | catalogued as rs782055614; called by mutect2, varscan2
- MAMDC2 | c.84T>C p.F28= | Silent (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- MYLK | c.1062G>A p.P354= | Silent (SNP) | VAF 49/119 reads (41%) | catalogued as rs149571440; called by muse, mutect2, varscan2
- OR1L8 | c.132G>A p.L44= | Silent (SNP) | VAF 42/138 reads (30%) | called by muse, mutect2, varscan2
- PADI2 | c.69C>G p.T23= | Silent (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- PSMG2 | c.720A>G p.V240= | Silent (SNP) | VAF 81/219 reads (37%) | called by muse, mutect2, varscan2
- ADCY1 | c.*1701C>T | 3'UTR (SNP) | VAF 25/66 reads (38%) | catalogued as rs1212054993; called by muse, mutect2, varscan2
- ADRA1A | c.*42C>T | 3'UTR (SNP) | VAF 68/186 reads (37%) | called by muse, varscan2
- ADRA1A | c.*41C>A | 3'UTR (SNP) | VAF 68/188 reads (36%) | called by muse, varscan2
- AFTPH | c.*740T>G | 3'UTR (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- ALDH3A2 | c.*1962T>C | 3'UTR (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- BMP6 | c.*985dup | 3'UTR (INS) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- C12orf43 | c.*736C>T | 3'UTR (SNP) | VAF 66/97 reads (68%) | catalogued as rs1002058403; called by muse, mutect2, varscan2
- C21orf91 | c.*4207A>G | 3'UTR (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- CDK20 | c.688-30A>G | Intron (SNP) | VAF 85/251 reads (34%) | called by muse, mutect2, varscan2
- CUL4A | c.149-42C>T | Intron (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- DGKB | c.*764G>T | 3'UTR (SNP) | VAF 44/151 reads (29%) | catalogued as COSV99338497; called by muse, mutect2, varscan2
- EIF5A2 | c.*2354T>A | 3'UTR (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- ELK3 | c.*579G>A | 3'UTR (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- ESR2 | chr14:64231815 A>C | 3'Flank (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- FCRL2 | c.-52C>T | 5'UTR (SNP) | VAF 206/809 reads (25%) | called by muse, mutect2, varscan2
- FCRL5 | c.*454C>G | 3'UTR (SNP) | VAF 84/313 reads (27%) | called by muse, varscan2
- FER | c.*4136T>G | 3'UTR (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- FKBP4 | c.-94C>T | 5'UTR (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- GBX2 | c.523+231G>A | Intron (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- GLIS3 | c.*157G>A | 3'UTR (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
- HEPH | chrX:66267926 del GAGAACAGAAGAGGTATCAAGGAGAGAAAAGAT | 3'Flank (DEL) | VAF 15/37 reads (41%) | called by mutect2, pindel
- HMGN2 | c.238-102A>T | Intron (SNP) | VAF 87/304 reads (29%) | called by muse, mutect2, varscan2
- KBTBD11 | c.*3765G>A | 3'UTR (SNP) | VAF 27/86 reads (31%) | catalogued as rs1469189608; called by muse, mutect2, varscan2
- KCNF1 | c.*179C>G | 3'UTR (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- LPCAT2 | c.*2186A>C | 3'UTR (SNP) | VAF 18/27 reads (67%) | called by muse, mutect2, varscan2
- LTB | c.163-134C>G | Intron (SNP) | VAF 81/269 reads (30%) | called by muse, varscan2
- MAP2 | c.*2951G>A | 3'UTR (SNP) | VAF 50/148 reads (34%) | called by muse, mutect2, varscan2
- MFSD1 | chr3:158801994 G>A | 5'Flank (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- MMP16 | c.*578C>T | 3'UTR (SNP) | VAF 46/92 reads (50%) | catalogued as rs28988883; called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142670816 C>T | 3'Flank (SNP) | VAF 67/197 reads (34%) | catalogued as rs1476017560; called by muse, mutect2, varscan2
- NEU4 | c.-165G>T | 5'UTR (SNP) | VAF 34/130 reads (26%) | catalogued as COSV57989916; called by muse, mutect2, varscan2
- NRBP2 | c.*414G>C | 3'UTR (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- NTRK2 | c.1585+5860C>T | Intron (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- NTS | c.*280C>A | 3'UTR (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- PCDH18 | c.*1387T>G | 3'UTR (SNP) | VAF 24/83 reads (29%) | called by muse, mutect2
- POFUT2 | c.1136+218G>A | Intron (SNP) | VAF 63/206 reads (31%) | called by muse, mutect2, varscan2
- PPP1R10 | c.853+24T>C | Intron (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- PSG4 | c.*263C>T | 3'UTR (SNP) | VAF 20/68 reads (29%) | called by mutect2, varscan2
- PSMC2 | chr7:103347519 C>G | 5'Flank (SNP) | VAF 68/243 reads (28%) | called by muse, mutect2, varscan2
- RBBP7 | c.758+103T>A | Intron (SNP) | VAF 14/20 reads (70%) | called by muse, mutect2, varscan2
- SEMA3D | c.*2237T>C | 3'UTR (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- SEZ6L | c.*1634G>A | 3'UTR (SNP) | VAF 153/453 reads (34%) | called by muse, mutect2, varscan2
- SPHK1 | chr17:76384051 T>G | 5'Flank (SNP) | VAF 38/103 reads (37%) | called by muse, mutect2, varscan2
- TDRD5 | c.*166G>T | 3'UTR (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- TGOLN2 | c.-124C>T | 5'UTR (SNP) | VAF 18/59 reads (31%) | catalogued as rs905320024; called by muse, mutect2, varscan2
- VWFP1 | n.1179A>C | RNA (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
